Somatic mutation profile of tumor specimen C3N-00715-01 (aliquot CPT0203930006) from CPTAC case C3N-00715, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-00715-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d53018e-f8bf-4d29-b022-4983a3338787.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00715-71 (Blood Derived Normal), aliquot CPT0203970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea64699b-9b8a-4008-b1c2-50f2a4de9544

The open-access MAF lists 94 somatic variants for this specimen: 66 protein-altering or splice-affecting, 15 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Intron 8, Nonsense Mutation 5, 3'UTR 3, RNA 2, Frame Shift Del 2, Splice Site 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.5927A>G p.K1976R | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1332336551; called by muse, mutect2
- CAPN15 | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 44/559 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as rs751850378; called by muse, mutect2
- DNAH12 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs143977508; called by muse, mutect2
- FEV | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 65/550 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55386546; called by muse, mutect2, varscan2
- JAG2 | c.1288A>T p.K430* | Nonsense Mutation (SNP) | VAF 30/446 reads (7%) | catalogued as rs781134028; called by muse, mutect2
- KRT16 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 78/858 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771112338; called by muse, varscan2
- LAX1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.294); catalogued as rs868657301; called by muse, mutect2, varscan2
- LRP1 | c.4469A>T p.E1490V | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54523904; called by muse, mutect2
- MARK4 | c.1922+1G>C p.X641_splice (on ENST00000262891 / NM_001199867.2; = p.X668_splice on NM_031417.4) | Splice Site (SNP) | VAF 8/91 reads (9%) | catalogued as COSV53469518; called by muse, mutect2
- MTOR | c.6050T>G p.I2017S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63878340, COSV63880423; called by muse, mutect2
- MYH8 | c.5144G>T p.R1715L | Missense Mutation (SNP) | VAF 44/544 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67965035; called by muse, mutect2
- ODF3L2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347327946; called by muse, mutect2
- OR4X2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs1005028891; called by muse, mutect2
- PSG3 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs746684780, COSV59507080; called by muse, mutect2
- RFXAP | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV55225969; called by muse, mutect2
- SLC18A1 | c.1329A>G p.I443M | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV52346605; called by muse, mutect2, varscan2
- TDRD5 | c.1926C>G p.N642K | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as COSV54245008, COSV99676002; called by muse, mutect2, varscan2
- TPR | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs1317504425; called by muse, mutect2
- ADGRG6 | c.2869del p.I957Lfs*3 | Frame Shift Del (DEL) | VAF 37/310 reads (12%) | called by mutect2, pindel, varscan2
- AGTPBP1 | c.1435G>T p.E479* (on ENST00000357081 / NM_001330701.2; = p.E439* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- ANO7 | c.1372G>T p.E458* (on ENST00000274979; = p.E404* on NM_001370694.2) | Nonsense Mutation (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- ATF4 | c.536G>C p.S179T | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.515); called by muse, mutect2
- ATP6V1B1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2
- B4GALT5 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CCT8L2 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2
- CFAP65 | c.437A>T p.E146V (on ENST00000341552 / NM_194302.4; = p.E81V on NM_152389.4) | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CLEC10A | c.46A>C p.K16Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.191); called by muse, mutect2
- CSMD2 | c.2629C>G p.Q877E | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.232); called by muse, mutect2
- CYFIP2 | c.3356T>A p.V1119D (on ENST00000616178 / NM_001291722.2; = p.V1094D on NM_014376.4) | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); called by muse, mutect2
- DRD3 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EDNRB | c.721_723del p.I241del (on ENST00000377211 / NM_001201397.1; = p.I151del on NM_000115.5) | In Frame Del (DEL) | VAF 28/298 reads (9%) | called by mutect2, pindel
- ELF3 | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- EPB41L5 | c.1226G>C p.W409S | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); called by muse, mutect2
- EVPL | c.2150T>C p.L717P | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FAM184B | c.2759G>C p.R920T | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2
- FBN3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GALNT13 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- GDPD4 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GET4 | c.605+2T>C p.X202_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | called by muse, varscan2
- GRM1 | c.1916T>A p.F639Y | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); called by muse, mutect2
- HFE | c.960G>T p.L320F | Missense Mutation (SNP) | VAF 60/630 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IFNA5 | c.246_250del p.E82Dfs*19 | Frame Shift Del (DEL) | VAF 24/260 reads (9%) | called by mutect2, pindel
- IRX6 | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 51/478 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- KIF5A | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 68/788 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KIF5A | c.1670A>T p.D557V | Missense Mutation (SNP) | VAF 70/791 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LTBP2 | c.4557C>A p.Y1519* | Nonsense Mutation (SNP) | VAF 41/376 reads (11%) | called by muse, mutect2, varscan2
- NDEL1 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.92); called by muse, mutect2
- NSD1 | c.6736C>T p.Q2246* | Nonsense Mutation (SNP) | VAF 39/568 reads (7%) | called by muse, mutect2
- NUP98 | c.3002A>G p.D1001G (on ENST00000359171 / NM_001365126.1; = p.D984G on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2
- OBSCN | c.14801A>T p.D4934V | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- OXGR1 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PEAR1 | c.2299C>A p.L767I | Missense Mutation (SNP) | VAF 101/629 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PEX13 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); called by muse, mutect2
- PIGW | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PLCB4 | c.3340A>C p.N1114H | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POLR3B | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2
- SCX | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.213); called by muse, mutect2
- SLC25A26 | c.374T>A p.F125Y | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC66A3 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SLCO5A1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPICE1 | c.1554C>A p.N518K | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- SQLE | c.1295G>T p.R432I | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by muse, mutect2
- TRIP6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- TRMT1 | c.252G>A p.L84= | Splice Region (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- TSPAN10 | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2
- ZXDC | c.1851G>T p.M617I | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2
- ANKRD62 | c.1992A>G p.L664= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs757364024; called by muse, mutect2, varscan2
- C6orf163 | c.925C>T p.L309= | Silent (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- CACNA1F | c.4830C>A p.A1610= | Silent (SNP) | VAF 52/236 reads (22%) | called by muse, mutect2, varscan2
- CARMIL2 | c.3270C>T p.V1090= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- DSTYK | c.1716C>A p.A572= | Silent (SNP) | VAF 24/350 reads (7%) | called by muse, mutect2
- ENPP6 | c.147T>C p.G49= | Silent (SNP) | VAF 44/442 reads (10%) | called by muse, mutect2
- KIAA1109 | c.4242G>C p.P1414= | Silent (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- LCT | c.2496G>A p.R832= | Silent (SNP) | VAF 24/376 reads (6%) | called by muse, mutect2
- LRCH3 | c.1431G>A p.E477= | Silent (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- LRRC10B | c.301C>A p.R101= | Silent (SNP) | VAF 22/242 reads (9%) | catalogued as rs1049241229; called by muse, mutect2
- PCDH1 | c.2376G>T p.V792= | Silent (SNP) | VAF 30/261 reads (11%) | called by muse, mutect2, varscan2
- PRSS53 | c.1548C>T p.A516= | Silent (SNP) | VAF 35/426 reads (8%) | called by muse, mutect2
- SBNO1 | c.4122A>G p.Q1374= (on ENST00000420886; = p.Q1373= on NM_018183.5) | Silent (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- SH3D19 | c.216T>C p.T72= | Silent (SNP) | VAF 17/171 reads (10%) | called by muse, mutect2, varscan2
- THSD7A | c.2688C>G p.T896= | Silent (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2
- AC099548.2 | n.1478C>A | RNA (SNP) | VAF 46/721 reads (6%) | called by muse, mutect2
- AC116351.1 | n.1084G>C | RNA (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- ACOXL | c.*1A>C | 3'UTR (SNP) | VAF 7/153 reads (5%) | called by muse, mutect2
- CHIT1 | c.*654C>G | 3'UTR (SNP) | VAF 29/475 reads (6%) | called by muse, mutect2
- DPP9 | c.1945-127del | Intron (DEL) | VAF 23/227 reads (10%) | called by mutect2, pindel, varscan2
- FAM20C | c.864-17636T>C | Intron (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- PRKACB | c.47-34713A>G | Intron (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- SHC4 | c.841-4432C>T | Intron (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- SNRNP70 | c.475+674_475+675del | Intron (DEL) | VAF 29/328 reads (9%) | called by mutect2, pindel
- TCIRG1 | c.630+34G>C | Intron (SNP) | VAF 39/488 reads (8%) | called by muse, mutect2
- TMEM236 | c.*2068C>G | 3'UTR (SNP) | VAF 14/241 reads (6%) | called by muse, mutect2
- UBXN2B | c.533+402A>G | Intron (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- ZC3H14 | c.80-141C>A | Intron (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
